Gene-level copy-number profile of tumor specimen ALCH-B2D1-TTP1-A from ALCHEMIST case ALCH-B2D1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 54.2 years (19,814 days).
Specimen ALCH-B2D1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4d324a52-839a-465c-a797-06362a0a0335.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2D1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/e2cd9680-feb2-45d9-8acd-68dd958d3481

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 4,231; copy number 2: 54,521; copy number 3: 45; copy number 4: 98.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,189,131–62,212,328, 5 genes: PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA.
- chr3:75,521,803–75,542,929, 2 genes (within-gene range 0–2): SNRPCP10, RPS3AP15.
- chr6:35,473,597–35,497,079, 1 gene: TEAD3.
- chr9:136,670,602–136,670,686, 1 gene (within-gene range 0–3): MIR126.
- chr10:86,668,507–86,736,072, 1 gene: LDB3.
- chr11:67,056,847–67,072,017, 1 gene: RHOD.
- chr20:3,227,417–3,245,382, 2 genes: SLC4A11, AL109976.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,381. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
